Somatic mutation profile of tumor specimen TCGA-SJ-A6ZJ-01A (aliquot TCGA-SJ-A6ZJ-01A-12D-A34Q-09) from TCGA case TCGA-SJ-A6ZJ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 61.9 years (22,597 days).
Specimen TCGA-SJ-A6ZJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f78cc793-cc49-46ce-83fd-6244ebddcc90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SJ-A6ZJ-10B (Blood Derived Normal), aliquot TCGA-SJ-A6ZJ-10B-01D-A34Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f6fb802-3d12-46f8-9913-74e2dc826997

The open-access MAF lists 75 somatic variants for this specimen: 52 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 22, Nonsense Mutation 4, Splice Site 2, In Frame Del 1, 5'UTR 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 15/50 reads (30%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- CTNNB1 | c.94G>C p.D32H | Missense Mutation (SNP) | VAF 17/50 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MYCN | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 3/11 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519919, COSV55257406, COSV55259752; ClinVar: likely pathogenic; called by muse, mutect2
- PTEN | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 18/74 reads (24%) | catalogued as rs786202840, COSV64292512, COSV64297236; ClinVar: pathogenic; called by muse, varscan2
- PTEN | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 49/87 reads (56%) | catalogued as rs371387815, CM110128, COSV64288370, COSV64295841; ClinVar: pathogenic; called by muse, varscan2
- ACP7 | c.461G>T p.R154L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs769422402, COSV100488536, COSV58700603; called by muse, mutect2, varscan2
- ANO5 | c.295-1G>C p.X99_splice | Splice Site (SNP) | VAF 10/32 reads (31%) | catalogued as CS122809, COSV100201960, COSV104410016; called by muse, mutect2, varscan2
- ARFGEF2 | c.2378C>T p.T793M | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs532986318, COSV100903921, COSV64213532; called by muse, mutect2, varscan2
- ASXL3 | c.3383G>A p.R1128Q | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.12); catalogued as rs772559746, COSV52475253; called by muse, mutect2, varscan2
- ATP10B | c.1768T>A p.C590S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100515216; called by muse, mutect2, varscan2
- ATP4B | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767846093, COSV100089770; called by muse, mutect2, varscan2
- CACNA1G | c.3496C>T p.R1166W | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.821); catalogued as rs372375481, COSV100662015; called by muse, mutect2, varscan2
- CDH2 | c.809A>C p.Q270P | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.625); catalogued as COSV99297326; called by muse, mutect2, varscan2
- CDH22 | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as rs202148153, COSV100952900; called by muse, mutect2, varscan2
- CFAP47 | c.153C>G p.D51E | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.946); catalogued as COSV52880099, COSV52882460; called by muse, mutect2, varscan2
- CYP26A1 | c.1109T>C p.V370A | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV99814800; called by muse, mutect2, varscan2
- FAT1 | c.11734C>A p.H3912N | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101499420; called by muse, mutect2, varscan2
- FBLIM1 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs137861374; called by muse, mutect2, varscan2
- GALNTL6 | c.1502G>T p.G501V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.696); catalogued as COSV101560315; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1115T>C p.V372A | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs1178688392, COSV100781502; called by muse, mutect2, varscan2
- JHY | c.2012C>T p.T671M | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368088863; called by muse, mutect2, varscan2
- LRPPRC | c.3838A>G p.I1280V | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.556); catalogued as rs1341770765, COSV99580880; called by muse, mutect2, varscan2
- LYPD3 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.08); catalogued as rs745685365, COSV54987883; called by muse, mutect2, varscan2
- MFSD1 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99963907; called by muse, mutect2, varscan2
- NCR1 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.938); catalogued as COSV52558760; called by muse, mutect2, varscan2
- NES | c.1913C>A p.S638Y | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV63960761; called by muse, mutect2, varscan2
- OBSCN | c.6509G>A p.R2170H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as rs542323662, COSV99477155; called by muse, mutect2, varscan2
- PASD1 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761622222, COSV64854816; called by muse, mutect2, varscan2
- PHKA1 | c.3350G>A p.R1117H | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.052); catalogued as rs143802511, COSV59806985; called by muse, mutect2, varscan2
- PI4KB | c.871C>T p.R291* (on ENST00000368873 / NM_001369623.1; = p.R303* on NM_002651.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 10/23 reads (43%) | catalogued as COSV55021152; called by muse, mutect2, varscan2
- POU4F2 | c.1036A>G p.K346E | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99850624; called by muse, mutect2, varscan2
- PTEN | c.492+1G>A p.X164_splice | Splice Site (SNP) | VAF 17/93 reads (18%) | catalogued as CD020869, COSV64293587, COSV64301805, COSV64306784; called by muse, mutect2, varscan2
- RARG | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.124); catalogued as COSV100553547; called by muse, mutect2, varscan2
- RDH10 | c.548C>T p.T183M | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs762042478, COSV99536357; called by muse, mutect2, varscan2
- RGMB | c.620G>A p.G207E (on ENST00000513185 / NM_001366508.1; = p.G248E on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1403366837, COSV100374902; called by muse, mutect2, varscan2
- SCN3A | c.3911G>A p.R1304Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51827816; called by muse, mutect2, varscan2
- SESN3 | c.1138C>T p.R380W | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV53584175; called by muse, mutect2, varscan2
- SLAMF9 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100928146, COSV63636424; called by muse, mutect2, varscan2
- SLC6A17 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58991663; called by muse, varscan2
- SOCS3 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1323259372, COSV100434480; called by muse, mutect2, varscan2
- SSB | c.437T>C p.L146S | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.721); catalogued as COSV99641752; called by muse, mutect2, varscan2
- TAF1L | c.3754C>T p.R1252W | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54259076; called by muse, mutect2, varscan2
- TAF7L | c.1273C>G p.L425V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.203); catalogued as rs192980404, COSV100229528; called by muse, mutect2, varscan2
- TIMM17B | c.137del p.H46Pfs*3 | Frame Shift Del (DEL) | VAF 30/90 reads (33%) | catalogued as COSV99503982; called by mutect2, pindel, varscan2
- TMCC3 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs764005646, COSV54156687; called by muse, varscan2
- UBA2 | c.1351A>T p.T451S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.168); catalogued as COSV99875598; called by muse, mutect2, varscan2
- ZNF19 | c.734A>G p.Y245C | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as COSV99867466; called by muse, mutect2, varscan2
- ZNF280D | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 19/55 reads (35%) | catalogued as rs756090139, COSV99974670; called by muse, mutect2, varscan2
- ZNF440 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.954); catalogued as COSV100407600; called by muse, mutect2, varscan2
- PGM5 | c.911A>T p.Q304L | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.158); called by muse, mutect2
- PIAS2 | c.214C>A p.L72I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.027); called by mutect2, varscan2
- PIK3R1 | c.1733_1742delinsG p.D578_L581delinsG (on ENST00000521381 / NM_181523.3; = p.D308_L311delinsG on NM_181504.4) | In Frame Del (DEL) | VAF 37/75 reads (49%) | called by pindel, varscan2*
- ABCB4 | c.1687T>C p.L563= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as rs370315075; called by muse, mutect2, varscan2
- AHNAK | c.3462C>T p.D1154= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as rs138130635; called by muse, mutect2, varscan2
- AKAP14 | c.294C>T p.G98= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as rs1362499527, COSV100538325; called by muse, mutect2, varscan2
- ARID5B | c.1839T>C p.D613= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV99689906; called by muse, mutect2, varscan2
- ASCC3 | c.1248A>G p.S416= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV100225917; called by muse, mutect2, varscan2
- ATIC | c.186G>A p.G62= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs777126703, COSV99377909; called by muse, mutect2, varscan2
- CLIP1 | c.4128C>G p.R1376= (on ENST00000620786 / NM_001247997.1; = p.R1365= on NM_002956.2) | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV100211909; called by muse, mutect2, varscan2
- ERF | c.1413A>T p.A471= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV99724708; called by muse, mutect2, varscan2
- GIMAP6 | c.129C>A p.L43= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100188278; called by muse, mutect2, varscan2
- HMGA1 | c.105G>A p.V35= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV100271769; called by muse, mutect2, varscan2
- KL | c.864C>G p.P288= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV101199118; called by muse, mutect2
- LILRA2 | c.498G>T p.L166= | Silent (SNP) | VAF 20/158 reads (13%) | catalogued as COSV99253538; called by muse, mutect2, varscan2
- MDN1 | c.8742C>G p.S2914= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV101021500; called by muse, mutect2, varscan2
- MYH2 | c.4152C>T p.D1384= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs779665835, COSV55448666; ClinVar: likely benign; called by muse, mutect2, varscan2
- NDUFA8 | c.159G>A p.P53= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV101056836; called by muse, mutect2, varscan2
- PCDHA13 | c.1734C>T p.S578= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as COSV56490478; called by muse, mutect2, varscan2
- PPP1R32 | c.528G>A p.T176= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs376746004; called by muse, mutect2, varscan2
- SEPTIN9 | c.1254C>G p.T418= (on ENST00000427177 / NM_001113491.2; = p.T400= on NM_006640.4) | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV100218161; called by muse, mutect2, varscan2
- SMG1 | c.594C>T p.D198= | Silent (SNP) | VAF 26/144 reads (18%) | catalogued as rs1053906712, COSV101246269; called by muse, mutect2
- TEKT5 | c.960G>A p.A320= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs541597767, COSV99296203; called by muse, mutect2, varscan2
- TFAP2B | c.831G>A p.S277= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as rs748267521, COSV53828573; called by muse, mutect2, varscan2
- ZFAND5 | c.531T>C p.L177= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as COSV99428537; called by muse, mutect2, varscan2
- CCDC70 | c.-23C>T | 5'UTR (SNP) | VAF 9/22 reads (41%) | catalogued as rs760757110, COSV99665377; called by muse, mutect2, varscan2
